Somatic mutation profile of tumor specimen 1105243 (aliquot 7316UP-8-1105243) from CPTAC case C247230, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G4.
Specimen 1105243: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96895823-1530-41fe-bc7a-a7daf2bac02c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105280 (Blood Derived Normal), aliquot 7316UP-243-1105280; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/44b81ca4-148b-4474-a2ef-2bfe9ab7a888

The open-access MAF lists 54 somatic variants for this specimen: 30 protein-altering or splice-affecting, 16 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 16, Intron 4, Nonsense Mutation 2, 3'UTR 2, Frame Shift Del 2, Splice Region 1, 5'Flank 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGB | c.4243G>A p.G1415R | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs958190580; called by muse, mutect2, varscan2
- ANKDD1B | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.123); catalogued as rs542617542, COSV72645528; called by muse, mutect2, varscan2
- CACNA2D4 | c.2587C>T p.R863C | Missense Mutation (SNP) | VAF 123/411 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as rs775588255; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC6 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 101/160 reads (63%) | SIFT tolerated (0.3); PolyPhen benign (0.338); catalogued as COSV54055823; called by muse, mutect2, varscan2
- CHGB | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 68/200 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.744); catalogued as rs373817587, COSV100972942; called by muse, mutect2, varscan2
- CYP2C18 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 158/292 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767161951; called by muse, mutect2, varscan2
- GBA | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 101/379 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.019); catalogued as rs748485792, CM140309, COSV59169558; called by muse, mutect2, varscan2
- GGT6 | c.526G>A p.G176S (on ENST00000574154 / NM_001122890.3; = p.G144S on NM_153338.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 195/446 reads (44%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as rs777856032; called by muse, mutect2, varscan2
- IGHM | c.1402G>A p.V468I | Missense Mutation (SNP) | VAF 93/329 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as rs772304630; called by muse, mutect2, varscan2
- LAD1 | c.566C>T p.T189M | Missense Mutation (SNP) | VAF 68/195 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs370468944; called by muse, mutect2, varscan2
- NUFIP2 | c.759del p.L254* | Frame Shift Del (DEL) | VAF 82/441 reads (19%) | catalogued as COSV99837110; called by mutect2, pindel, varscan2
- RYR1 | c.6445G>A p.V2149M | Missense Mutation (SNP) | VAF 217/751 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs776830747, COSV62109696; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SUDS3 | c.961G>A p.V321M | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.538); catalogued as COSV64349096; called by muse, mutect2, varscan2
- VPS13D | c.3943C>T p.R1315* | Nonsense Mutation (SNP) | VAF 70/241 reads (29%) | catalogued as rs1014084562, COSV50691564; called by muse, mutect2, varscan2
- WDR64 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.301); catalogued as rs1302850245, COSV63793738, COSV63796103; called by muse, mutect2, varscan2
- ZNF461 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs1356093352, COSV64453450; called by muse, mutect2
- ZSWIM4 | c.2035C>T p.R679W | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1007165557; called by muse, mutect2, varscan2
- CHD7 | c.3799G>C p.E1267Q | Missense Mutation (SNP) | VAF 65/206 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- DNAJC11 | c.1323+5G>T | Splice Region (SNP) | VAF 27/70 reads (39%) | called by muse, mutect2, varscan2
- EQTN | c.224C>G p.P75R | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- FAM71E2 | c.585T>G p.H195Q | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.084); called by muse, varscan2
- GIGYF2 | c.2326G>T p.E776* | Nonsense Mutation (SNP) | VAF 102/350 reads (29%) | called by muse, mutect2, varscan2
- LCP1 | c.1437_1439del p.G480del | In Frame Del (DEL) | VAF 50/241 reads (21%) | called by mutect2, pindel, varscan2
- LIPE | c.1468G>A p.V490M | Missense Mutation (SNP) | VAF 65/240 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- MLLT3 | c.295C>G p.R99G | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- MYO1H | c.1142C>T p.S381F | Missense Mutation (SNP) | VAF 54/211 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCOA2 | c.2693G>C p.G898A | Missense Mutation (SNP) | VAF 92/344 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTEN | c.55del p.D19Mfs*5 | Frame Shift Del (DEL) | VAF 180/406 reads (44%) | called by mutect2, pindel, varscan2
- SLC25A52 | c.409C>T p.L137F (on ENST00000672005; = p.L127F on NM_001034172.4) | Missense Mutation (SNP) | VAF 74/231 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- ZNF701 | c.1181G>T p.C394F (on ENST00000301093; = p.C328F on NM_018260.3) | Missense Mutation (SNP) | VAF 12/348 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRG4 | c.5910C>T p.D1970= | Silent (SNP) | VAF 58/102 reads (57%) | catalogued as rs760543724, COSV54949082; called by muse, mutect2, varscan2
- ANK1 | c.1866G>A p.L622= | Silent (SNP) | VAF 117/456 reads (26%) | catalogued as rs776247811; called by muse, mutect2, varscan2
- ANKMY2 | c.1266C>T p.S422= | Silent (SNP) | VAF 24/104 reads (23%) | catalogued as rs771684492, COSV61011359; called by muse, mutect2, varscan2
- ANKS4B | c.84G>A p.S28= | Silent (SNP) | VAF 45/213 reads (21%) | catalogued as rs376343890; called by muse, mutect2, varscan2
- ARSH | c.321C>T p.G107= | Silent (SNP) | VAF 59/99 reads (60%) | called by muse, mutect2, varscan2
- ASXL1 | c.1830C>T p.G610= | Silent (SNP) | VAF 108/413 reads (26%) | catalogued as rs199829982; called by muse, mutect2, varscan2
- DAW1 | c.1197C>T p.G399= | Silent (SNP) | VAF 43/124 reads (35%) | called by muse, mutect2, varscan2
- KRT19 | c.723G>A p.P241= | Silent (SNP) | VAF 73/337 reads (22%) | catalogued as rs140667731; called by muse, mutect2, varscan2
- OR10R2 | c.783C>T p.C261= | Silent (SNP) | VAF 55/133 reads (41%) | catalogued as rs753353295, COSV63769299, COSV63769398; called by muse, mutect2, varscan2
- OR2T10 | c.313C>T p.L105= | Silent (SNP) | VAF 83/260 reads (32%) | catalogued as COSV57897015, COSV57897073; called by muse, mutect2, varscan2
- OXSR1 | c.264G>A p.L88= | Silent (SNP) | VAF 85/228 reads (37%) | catalogued as COSV61259203; called by muse, mutect2, varscan2
- PCDHGB3 | c.1869G>A p.T623= | Silent (SNP) | VAF 75/244 reads (31%) | catalogued as COSV53937747; called by muse, mutect2, varscan2
- PLCG2 | c.2409C>T p.P803= | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as rs774918375; called by muse, mutect2, varscan2
- SLC27A2 | c.831C>T p.H277= | Silent (SNP) | VAF 56/157 reads (36%) | catalogued as rs79765607; called by muse, mutect2, varscan2
- TMEM147 | c.481C>T p.L161= | Silent (SNP) | VAF 99/330 reads (30%) | called by muse, mutect2, varscan2
- USH2A | c.14073C>T p.N4691= | Silent (SNP) | VAF 48/198 reads (24%) | catalogued as rs370364142, COSV56342993; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ACADVL | c.*51G>C | 3'UTR (SNP) | VAF 151/319 reads (47%) | called by muse, mutect2, varscan2
- ANKRD18A | chr9:38621264 G>C | 5'Flank (SNP) | VAF 117/375 reads (31%) | catalogued as rs1457530152; called by muse, mutect2, varscan2
- EFHC1 | c.*3181G>T | 3'UTR (SNP) | VAF 30/432 reads (7%) | called by muse, mutect2
- LGI4 | c.1300-233C>T | Intron (SNP) | VAF 18/75 reads (24%) | called by muse, mutect2, varscan2
- NADSYN1 | c.146+9A>G | Intron (SNP) | VAF 33/99 reads (33%) | called by muse, mutect2, varscan2
- PAFAH1B2 | chr11:117174909 C>G | 3'Flank (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2, varscan2
- PCLO | c.13655-1671G>T | Intron (SNP) | VAF 5/76 reads (7%) | called by muse, mutect2
- PNPLA7 | c.1151-3595G>C | Intron (SNP) | VAF 37/110 reads (34%) | called by muse, mutect2, varscan2
